Surgical pathology report (de-identified scan), TCGA case TCGA-UT-A88D, project TCGA-MESO (Mesothelioma), tissue source site Asbestos Diseases Research Institute, specimen TCGA-UT-A88D-01B (Primary Tumor).

HISTOPATHOLOGY REPORT :

CLINICAL NOTES:

Probable mesothelioma

MACROSCOPIC:

'Parietal pleura'. The specimen consists of five irregular pink membranous pieces of tissue measuring between 3mm and 18x10x3mm in maximal dimension, each bearing firm thickened white nodules measuring between 2mm and 5mm in maximal dimension. All embedded. (Block A and B - 4p each, C - 3p). A PAS diastase has been requested in each block.

MICROSCOPIC:

Sections of pleura including pleural adipose tissue contain a malignant infiltrate. The malignant are arranged in cohesive aggregates with tubulopapillary clefts and micropapillary areas. The epithelioid cells have large irregular nuclei with prominent nucleoli and a variable amount of eosinophilic to clear cytoplasm. There is a background fibrous stroma. The malignant cells infiltrate between islands of fat cells. Areas of fat necrosis are also present. No intracytoplasmic mucin is seen on PAS diastase stain.

Immunohistochemical stains show that the malignant cells are positive for CK5/6 and HBME1, and negative for TTF1, MOC31 and monoclonal CEA. The histological features and immunohistochemical profile is compatible with malignant mesothelioma of epithelioid type.

DIAGNOSIS:

PARIETAL PLEURA - MALIGNANT MESOTHELIOMA, EPITHELIOID SUBTYPE

Reported by

ICD-O-3

Mesothelioma, epithelioid, malignant 9652/3

Site CCLF

Pleura C 88.4

path

Parietal pleura C 88.4
9/10/2013

Surge
Use

Norm

No-Act
File

Cont
Patien

See
Patien

See F

Cont
Treatm

Signe

Date

Source: NCI Genomic Data Commons file 5b649357-dfc1-45ee-a1bd-d416b7e3365f (TCGA-UT-A88D.4C85EB8F-AC6C-4DD6-8B53-378667002491.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).